Somatic mutation profile of tumor specimen TCGA-BR-8381-01A (aliquot TCGA-BR-8381-01A-11D-2394-08) from TCGA case TCGA-BR-8381, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 51.6 years (18,843 days).
Specimen TCGA-BR-8381-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 076beb5c-cee7-40eb-b7f9-be4ef22114fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8381-10A (Blood Derived Normal), aliquot TCGA-BR-8381-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7295c7c7-99a7-4a4b-893e-5a1959b01f84

The open-access MAF lists 125 somatic variants for this specimen: 89 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 32, Nonsense Mutation 4, Splice Region 3, Intron 2, 5'Flank 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.13450C>T p.R4484* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as rs587783690, CM111921, COSV56434635; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.72C>G p.D24E | Missense Mutation (SNP) | VAF 5/87 reads (6%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs1320222638, COSV64288999; ClinVar: uncertain significance; called by muse, mutect2
- AATK | c.2932C>T p.R978W (on ENST00000326724 / NM_001080395.3; = p.R875W on NM_004920.2) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs368177200; called by muse, mutect2, varscan2
- ABCC3 | c.3026C>T p.S1009F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV53316785; called by muse, mutect2, varscan2
- ABCC9 | c.484A>C p.I162L | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV53976766; called by muse, mutect2
- ARHGEF17 | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as rs1298383300, COSV55234204; called by muse, mutect2
- ARID1A | c.6791C>A p.S2264* | Nonsense Mutation (SNP) | VAF 12/166 reads (7%) | catalogued as COSV61372401, COSV61380775, COSV61381424; called by muse, mutect2
- ASTN2 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs138260564; called by muse, mutect2, varscan2
- CARD16 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.042); catalogued as COSV65213138; called by muse, mutect2
- CAV1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV100591899, COSV61953732; called by muse, mutect2
- CCND2 | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs149961693, COSV54222002; called by muse, mutect2, varscan2
- CHGB | c.282A>C p.E94D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as COSV66760907; called by muse, mutect2, varscan2
- CHIA | c.918C>A p.I306= (on ENST00000343320; = p.I198= on NM_021797.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100588545; called by muse, mutect2, varscan2
- CHPF2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs148527739; called by muse, mutect2
- CLCN5 | c.2148C>T p.N716= | Splice Region (SNP) | VAF 3/22 reads (14%) | catalogued as rs782105613, COSV56582442; called by muse, mutect2
- CNTN4 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1199542195, COSV68561856; called by muse, mutect2, varscan2
- CREB5 | c.1322G>T p.C441F (on ENST00000357727 / NM_182898.4; = p.C434F on NM_004904.3) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63223575; called by muse, mutect2
- DDX58 | c.2604C>G p.N868K | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV59381270; called by muse, mutect2
- DISP1 | c.4513G>A p.V1505M | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV52661271; called by muse, mutect2
- DNAH8 | c.3998T>G p.L1333W | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.926); catalogued as COSV59459144, COSV59471370; called by muse, mutect2
- DNAJB5 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1176016786, COSV56626368; called by muse, mutect2, varscan2
- DNAJC14 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); catalogued as COSV57913454; called by muse, mutect2
- EP300 | c.4388T>G p.L1463R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54336565, COSV99607535; called by muse, mutect2
- ERBB3 | c.941A>C p.K314T | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV57256977; called by muse, mutect2, varscan2
- FAT3 | c.8750T>A p.I2917K | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV53133496; called by muse, mutect2
- FGFR4 | c.1933A>G p.K645E | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52805591; called by muse, mutect2, varscan2
- FIBIN | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs927935181, COSV59413125; called by muse, mutect2, varscan2
- FSHR | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58627202; called by muse, mutect2, varscan2
- GABRA1 | c.742A>G p.R248G | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50109426; called by muse, mutect2
- GABRG3 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1566912903, COSV61516563; called by muse, mutect2, varscan2
- GPR6 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51572621; called by muse, mutect2, varscan2
- INO80 | c.4349G>A p.R1450Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV62739494; called by muse, mutect2
- IRX5 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58059346; called by muse, mutect2, varscan2
- JAK3 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as CM163205, COSV71685396; called by muse, mutect2, varscan2
- KCNS2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54639331; called by muse, mutect2
- KMT2B | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs746908334, COSV52890088; called by muse, mutect2, varscan2
- LIG4 | c.2612G>A p.R871H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as rs183928755, COSV63597394; called by muse, mutect2, varscan2
- LRRC7 | c.1883C>T p.P628L (on ENST00000651989 / NM_001370785.2; = p.P595L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs775100037, COSV50496226; called by muse, mutect2, varscan2
- LRRC7 | c.3176C>A p.A1059D (on ENST00000651989 / NM_001370785.2; = p.A1026D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as COSV50496373; called by muse, mutect2, varscan2
- LRRK2 | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV54158938; called by muse, mutect2
- MCF2L2 | c.2654G>A p.R885Q | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs780301597, COSV61054485; called by muse, mutect2, varscan2
- MCTP1 | c.1862A>G p.N621S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as rs375290165; called by muse, mutect2, varscan2
- MDN1 | c.6520C>G p.L2174V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV65522502; called by muse, mutect2
- MED7 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs138235255; called by muse, mutect2, varscan2
- MEFV | c.2110G>A p.V704I | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs104895096, CM012154, COSV54820562; ClinVar: uncertain significance; called by muse, mutect2
- MSR1 | c.1111T>A p.W371R | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746464687, COSV50516915, COSV50529667; called by muse, mutect2
- NEK10 | c.3502C>T p.H1168Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55361026; called by muse, mutect2, varscan2
- NFASC | c.2386C>T p.P796S (on ENST00000339876 / NM_001378329.1; = p.P792S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV58369934; called by muse, mutect2, varscan2
- NFATC1 | c.472A>C p.S158R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.052); catalogued as COSV53703364; called by muse, mutect2, varscan2
- NID2 | c.228C>T p.Y76= | Splice Region (SNP) | VAF 12/74 reads (16%) | catalogued as rs1417868011, COSV53498834; called by muse, mutect2, varscan2
- NOS1AP | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 12/151 reads (8%) | catalogued as COSV62636606; called by muse, mutect2
- NRXN2 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55456719; called by muse, mutect2, varscan2
- NUP210 | c.2593G>C p.E865Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV54408622, COSV54412835; called by muse, mutect2, varscan2
- OR56B1 | c.395A>T p.Y132F | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV57723394; called by muse, mutect2, varscan2
- OR5A1 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV57377163; called by muse, mutect2
- OR7A10 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.433); catalogued as rs576280843, COSV50166468; called by muse, mutect2, varscan2
- OXCT1 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.059); catalogued as COSV52172980; called by muse, mutect2, varscan2
- PPARGC1A | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs748836875, COSV53529710; called by muse, mutect2
- PRDM9 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV104393150; called by muse, mutect2, varscan2
- PRDM9 | c.2370C>A p.N790K | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs1172009382, COSV57008573; called by muse, mutect2
- PRKAR1B | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs1374209048, COSV64319131; called by muse, mutect2
- RAB27A | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs104894499, CM001324, COSV61016563; called by muse, mutect2
- RAPGEF5 | c.625G>A p.D209N (on ENST00000401957 / NM_001367602.2; = p.D512N on NM_012294.5) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV59786463; called by muse, mutect2, varscan2
- RELA | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.711); catalogued as rs756811835, COSV58015204; called by muse, mutect2, varscan2
- RRAGD | c.202A>G p.M68V | Missense Mutation (SNP) | VAF 49/429 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1201326764, COSV63269511; called by muse, mutect2, varscan2
- RUNX1T1 | c.1183C>T p.R395W (on ENST00000265814 / NM_001198628.1; = p.R368W on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1448417558, COSV56155622; called by muse, mutect2
- RXFP3 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1387893679, COSV57506113, COSV57506563; called by muse, mutect2, varscan2
- SEC16A | c.2936A>G p.N979S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV51531985; called by mutect2, varscan2
- SLC26A7 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52596927; called by muse, mutect2
- SLC30A3 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs529940740, COSV51986407; called by muse, mutect2, varscan2
- SLITRK6 | c.153A>T p.K51N | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV68390619; called by muse, mutect2
- SNTG1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52453720; called by muse, mutect2, varscan2
- SYTL2 | c.2467G>T p.D823Y (on ENST00000528231 / NM_001162951.2; = p.D799Y on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60360559; called by muse, mutect2
- TAF2 | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as COSV65419041; called by muse, mutect2
- TBX5 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100092091, COSV59862667; called by muse, mutect2, varscan2
- TCERG1L | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1020686803, COSV64048724; called by muse, mutect2, varscan2
- TCHH | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as COSV64273841; called by muse, mutect2, varscan2
- TECRL | c.429G>A p.W143* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV67086328, COSV67086998, COSV67088225; called by muse, mutect2, varscan2
- TRIM9 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.774); catalogued as rs1566660109, COSV53619669; called by muse, mutect2, varscan2
- USP5 | c.2152G>A p.A718T (on ENST00000229268 / NM_001098536.2; = p.A695T on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs202087351, COSV57538397; called by muse, varscan2
- UTRN | c.9199C>A p.Q3067K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV62304620, COSV62304670; called by muse, mutect2, varscan2
- WDSUB1 | c.691T>C p.Y231H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.757); catalogued as COSV63067576; called by muse, mutect2, varscan2
- HUWE1 | c.567+2_567+17del p.X189_splice | Splice Site (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- MYO6 | c.2528T>G p.V843G | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2
- NCOA4 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2B2 | c.593A>C p.E198A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, varscan2
- SH3GL2 | c.906A>T p.E302D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SPANXB1 | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 26/579 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- USH2A | c.10046_10073del p.K3349Tfs*22 | Frame Shift Del (DEL) | VAF 18/186 reads (10%) | called by mutect2, pindel
- ACP2 | c.969C>T p.F323= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV57039511, COSV57039774; called by muse, mutect2
- ADAM23 | c.843G>A p.L281= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV52219857; called by muse, mutect2, varscan2
- ANKRD7 | c.495C>T p.A165= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV54555414; called by muse, mutect2, varscan2
- APBA2 | c.351C>T p.N117= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs772215906, COSV68790870; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASMTL | c.1650C>T p.A550= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs768866350, COSV67244211; called by muse, mutect2, varscan2
- CNOT3 | c.1935G>A p.T645= | Silent (SNP) | VAF 9/172 reads (5%) | catalogued as rs202216847; called by muse, mutect2
- COL22A1 | c.1053C>T p.F351= | Silent (SNP) | VAF 24/153 reads (16%) | catalogued as COSV57344489; called by muse, mutect2, varscan2
- COL4A6 | c.3627A>G p.K1209= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV57870392; called by muse, mutect2, varscan2
- CPA4 | c.1200C>G p.P400= | Silent (SNP) | VAF 10/192 reads (5%) | catalogued as COSV55983924; called by muse, mutect2
- DCLK3 | c.772A>C p.R258= | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as COSV69363782; called by muse, mutect2
- DUS3L | c.798C>T p.P266= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs748788604, COSV57832372; called by muse, mutect2
- EXOC4 | c.492G>A p.L164= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV54105798; called by muse, mutect2, varscan2
- FLG2 | c.2874C>A p.S958= | Silent (SNP) | VAF 70/671 reads (10%) | catalogued as rs529976530, COSV66169905; called by muse, mutect2, varscan2
- FLRT3 | c.1947A>C p.S649= | Silent (SNP) | VAF 19/212 reads (9%) | catalogued as COSV54007437; called by muse, mutect2
- GIT1 | c.1285C>T p.L429= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs751546077, COSV56403032; called by muse, mutect2, varscan2
- LRP1 | c.12984C>T p.C4328= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV54516549; called by muse, mutect2, varscan2
- MCM8 | c.1134G>A p.K378= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as COSV54515681; called by muse, mutect2, varscan2
- MPV17L | c.441A>G p.Q147= (on ENST00000396385 / NM_001128423.2; = p.M124V on NM_173803.4) | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs756473622, COSV55008662; called by muse, mutect2, varscan2
- MUC17 | c.9606T>G p.T3202= | Silent (SNP) | VAF 68/565 reads (12%) | called by muse, mutect2, varscan2
- MXRA5 | c.8250C>T p.T2750= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs760983208, COSV54240280; called by muse, mutect2, varscan2
- NODAL | c.960G>A p.P320= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as rs959419966, COSV54661786; called by muse, mutect2, varscan2
- OR2T35 | c.771C>T p.Y257= | Silent (SNP) | VAF 4/106 reads (4%) | called by muse, mutect2
- OR8J3 | c.207C>A p.I69= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV56879840; called by muse, mutect2
- PCDHB4 | c.300G>A p.P100= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV52020304; called by muse, mutect2, varscan2
- PPFIA2 | c.2511G>A p.L837= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as COSV61039530; called by muse, mutect2
- SLC32A1 | c.111G>A p.T37= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs756349613, COSV54147308; called by muse, mutect2, varscan2
- SLITRK5 | c.1284C>T p.D428= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV61523810; called by muse, mutect2, varscan2
- TCP11L2 | c.1059G>A p.V353= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV54430992; called by muse, mutect2
- TSSC4 | c.609G>A p.Q203= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV50160928; called by muse, mutect2, varscan2
- WNK2 | c.2571G>A p.Q857= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV52947524; called by muse, mutect2, varscan2
- ZFP30 | c.597C>T p.A199= | Silent (SNP) | VAF 13/147 reads (9%) | catalogued as COSV63622772; called by muse, mutect2
- ZNF280C | c.2046C>A p.G682= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV63969283; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501143 C>T | 5'Flank (SNP) | VAF 6/63 reads (10%) | catalogued as rs539201929; called by muse, mutect2, varscan2
- CAPZB | c.4-29137T>G | Intron (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99940456; called by mutect2, varscan2
- POLR3D | chr8:22245028 C>T | 5'Flank (SNP) | VAF 25/128 reads (20%) | catalogued as rs1302873200; called by muse, mutect2, varscan2
- SKA2 | c.33+69A>G | Intron (SNP) | VAF 29/167 reads (17%) | catalogued as COSV99231373; called by muse, mutect2, varscan2
